Somatic mutation profile of tumor specimen TCGA-BP-4981-01A (aliquot TCGA-BP-4981-01A-01D-1462-08) from TCGA case TCGA-BP-4981, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 75.8 years (27,676 days).
Specimen TCGA-BP-4981-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15922ef0-f31a-4208-8da5-9a63de635195.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4981-11A (Solid Tissue Normal), aliquot TCGA-BP-4981-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1160cc4-5ba5-47df-9971-afbd5ba60dd0

The open-access MAF lists 55 somatic variants for this specimen: 39 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 15, Nonsense Mutation 2, Frame Shift Del 2, Frame Shift Ins 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRE3 | c.1329C>A p.H443Q | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV53734329; called by muse, mutect2, varscan2
- AHNAK2 | c.11126G>A p.G3709D | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV60928558; called by muse, mutect2, varscan2
- ASXL2 | c.2054C>G p.S685* | Nonsense Mutation (SNP) | VAF 49/154 reads (32%) | catalogued as COSV55466805; called by muse, mutect2, varscan2
- BOD1L1 | c.6439A>G p.S2147G | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50052947; called by muse, mutect2, varscan2
- CDH11 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1234130665, COSV51775482; called by muse, mutect2, varscan2
- COL4A5 | c.3551C>T p.P1184L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60370432; called by muse, mutect2, varscan2
- ERCC6 | c.429T>G p.C143W | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV63393846; called by muse, mutect2, varscan2
- ESPL1 | c.4787T>C p.L1596P | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57762819; called by muse, mutect2, varscan2
- F10 | c.969C>G p.I323M | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV65022878; called by muse, mutect2
- FLG | c.1488C>A p.H496Q | Missense Mutation (SNP) | VAF 144/435 reads (33%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.766); catalogued as rs1158828571, COSV64247743; called by muse, mutect2, varscan2
- GADL1 | c.1535A>G p.D512G | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as COSV56984843; called by muse, mutect2
- HMCN1 | c.6568A>C p.N2190H | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54935653; called by muse, mutect2, varscan2
- HSP90AA1 | c.608T>C p.I203T | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV53491104; called by muse, mutect2, varscan2
- INTU | c.1226A>T p.Q409L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV58874254; called by muse, mutect2, varscan2
- KIF14 | c.944A>T p.Q315L | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV66263818; called by muse, mutect2, varscan2
- KPNA4 | c.108A>C p.L36F | Missense Mutation (SNP) | VAF 21/309 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV62076880; called by muse, mutect2
- MKNK1 | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57862771; called by muse, mutect2, varscan2
- MRPS22 | c.908A>G p.Y303C (on ENST00000310776 / NM_001363893.1; = p.Y304C on NM_020191.4) | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60351123; called by muse, mutect2, varscan2
- MTCH2 | c.478T>C p.C160R | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV56768675; called by muse, mutect2, varscan2
- P2RX2 | c.1206G>T p.K402N (on ENST00000343948 / NM_170683.4; = p.K304N on NM_012226.5) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV57689222; called by muse, mutect2, varscan2
- PBRM1 | c.1442del p.Q481Rfs*19 | Frame Shift Del (DEL) | VAF 38/101 reads (38%) | catalogued as COSV56300914; called by mutect2, pindel, varscan2
- PHF20 | c.1441A>T p.K481* | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as COSV59188473; called by muse, mutect2, varscan2
- PLSCR5 | c.233T>G p.M78R | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV71649214; called by muse, mutect2, varscan2
- PRKCH | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.472); catalogued as COSV60648024; called by muse, mutect2
- RDH16 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs368973096; called by muse, mutect2, varscan2
- SIGLEC11 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1282751924, COSV70222128; called by muse, mutect2
- SIMC1 | c.2413C>T p.P805S (on ENST00000443967 / NM_001308196.1; = p.P390S on NM_198567.5) | Missense Mutation (SNP) | VAF 113/218 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs772659403, COSV53799978; called by muse, mutect2, varscan2
- SMPD1 | c.1628A>T p.E543V | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as COSV54970404; called by muse, mutect2, varscan2
- STKLD1 | c.804A>C p.E268D | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV64314749; called by muse, mutect2, varscan2
- THEG | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.086); catalogued as COSV61074784; called by muse, mutect2, varscan2
- TNS3 | c.2509A>G p.S837G | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60798172; called by muse, varscan2
- UCK1 | c.227A>C p.K76T | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV64736248; called by muse, mutect2, varscan2
- UTP3 | c.1392A>C p.E464D | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54661824; called by muse, mutect2, varscan2
- VAV1 | c.1237T>C p.S413P | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV58390807; called by muse, mutect2, varscan2
- VCL | c.2005C>G p.R669G | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV53014036, COSV53014687; called by muse, mutect2, varscan2
- VMP1 | c.1077+2T>C p.X359_splice | Splice Site (SNP) | VAF 37/95 reads (39%) | catalogued as COSV51871811; called by muse, mutect2, varscan2
- ZNF148 | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 116/329 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV62307339; called by muse, mutect2, varscan2
- FAM193A | c.1065dup p.A356Sfs*2 | Frame Shift Ins (INS) | VAF 86/267 reads (32%) | called by mutect2, pindel, varscan2
- RTKN2 | c.451del p.T151Qfs*10 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- ABCA13 | c.4692C>T p.N1564= | Silent (SNP) | VAF 86/249 reads (35%) | catalogued as COSV70042295; called by muse, mutect2, varscan2
- ANKRD12 | c.468T>C p.H156= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs758351899, COSV50843989; called by muse, mutect2, varscan2
- CHGB | c.324G>A p.G108= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV66761593; called by muse, mutect2
- CYP4A11 | c.597G>A p.K199= | Silent (SNP) | VAF 57/174 reads (33%) | catalogued as rs1182138140, COSV60225281; called by muse, mutect2, varscan2
- DOT1L | c.1845G>A p.S615= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs777836214, COSV67112905; called by muse, mutect2, varscan2
- GCC2 | c.3924T>A p.A1308= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV59179551; called by muse, mutect2, varscan2
- KDM5A | c.1578T>C p.F526= | Silent (SNP) | VAF 55/141 reads (39%) | catalogued as COSV66995869; called by muse, mutect2, varscan2
- MC3R | c.198C>T p.N66= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as rs961326205, COSV54763540; called by muse, mutect2, varscan2
- METTL9 | c.69G>C p.T23= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs1355724232, COSV63962752; called by muse, mutect2, varscan2
- MSLN | c.1362C>G p.P454= (on ENST00000382862 / NM_013404.4; = p.P446= on NM_005823.6) | Silent (SNP) | VAF 49/198 reads (25%) | catalogued as rs201168564, COSV53505763; called by muse, mutect2, varscan2
- MUC16 | c.41130C>T p.H13710= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as COSV66695954; called by muse, mutect2
- PCDHA12 | c.540T>G p.L180= | Silent (SNP) | VAF 80/130 reads (62%) | catalogued as COSV56540083; called by muse, varscan2
- PCID2 | c.75T>C p.C25= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV55814991; called by muse, mutect2, varscan2
- PKP2 | c.2385C>T p.A795= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as COSV50745231; called by muse, mutect2, varscan2
- TINAG | c.801T>C p.N267= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as COSV52514144; called by muse, mutect2, varscan2
- ASPH | c.322+4700T>C | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as COSV62861130; called by muse, mutect2, varscan2
